Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YI-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED] Accession #: [REDACTED]
Med. Rec. #: [REDACTED] Client: [REDACTED]
DOB: [REDACTED] Location: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Vaginal bleeding, breast cancer, family history of cancer

Postoperative Dx: Same, pending pathology examination

ICD-9-3 not applicable.

Specimen(s) Received:

Uterus, cervix, tubes and ovaries

Normal path from a non-cancer patient.

for 11/1/11

DIAGNOSIS:

Uterus, cervix, tubes and ovaries:

Cervix: Chronic cervicitis
Endometrium: Poorly developed secretory endometrium
Myometrium: Intramural leiomyoma and adenomyosis
Right ovary: Ovarian tissue with physiologic changes
Right tube: Unremarkable
Left ovary: Ovarian tissue with physiologic changes
Left tube: Unremarkable

Gross Description

Received: Formalin is a single piece of unoriented, previously opened soft tan to pink tissue
Labeled: "cervix, uterus, bilateral ovaries and tubes"
Weight: 168 gm
Size
Uterus: 10.4 x 7.7 x 4.9 cm
Right ovary: 2.5 x 1.6 x 0.8 cm
Left ovary: 2.6 x 1.6 x 1.5 cm
Appearance
Serosal surface: Smooth with ragged areas, no subserosal bulging
Cervix: Grossly unremarkable
Endometrium: 0.2 cm in thickness, smooth, shiny, tan with no papillary or thickened areas grossly identified
Myometrium: 2.2 cm in thickness. Possible area of adenomyosis, 2.0 x 1.4 x 0.5 cm.
Right tube and ovary: The tube measures 6.1 x 0.5 x 0.5 cm and is grossly unremarkable, with no paratubal cystic structures grossly identified. The ovary shows a white homogenous cut surface, with no cystic structures grossly identified.

Supplementary Statements:

The following statement may be applicable to each of the individual specimens received in this report. This report was prepared and its contents verified by a pathologist who is a member of the American Board of Clinical Pathology. The ICD-9-3 code assigned to each specimen is provided for your reference. This report is valid for clinical purposes. It should not be regarded as a substitute for a complete clinical history. The laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

Left tube and ovary:

(inked blue) The tube measures 4.2 x 0.5 x 0.5 cm. and is grossly unremarkable with no paratubal cystic structures grossly identified. The ovary shows a white, homogenous cut surface with no cystic structures grossly identified.

Myomas

Number:

1

Size:

0.3 x 0.3 x 0.3 cm.

Appearance:

Well-circumscribed, white with a whorled cut surface

Other:

There is an apparent intrauterine device, measuring 3.7 x 2.6 x 0.2 cm.

Key to cassettes:

1 -

Cervix

2 -

Lower uterine segment, full thickness

3-5-

Endomyometrium

6 -

Myoma

7 -

Areas of possible adenomyosis

8 -

Right and left adnexa (left adnexa inked blue)

Microscopic Description

The microscopic findings support the above diagnoses.

Source: NCI Genomic Data Commons file 67c5b900-91dc-4eda-b805-f1888faa4221 (TCGA-FL-A1YI.BC17ABB4-DBAA-43FD-BBBA-C48C71BEDE62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).